Gene-level copy-number profile of tumor specimen TCGA-G4-6303-01A from TCGA case TCGA-G4-6303, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 54.2 years (19,800 days).
Specimen TCGA-G4-6303-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.232b4ad2-d88a-441e-868a-f3de94714423.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G4-6303-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4cd7484b-04a2-40da-99d7-4ccd40285530

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 753; copy number 2: 10,009; copy number 3: 28,545; copy number 4: 14,999; copy number 5: 2,004; copy number 6: 2,056; copy number 7: 302; copy number 8: 284; copy number 9: 607; copy number 11: 81; copy number 14: 149; copy number 16: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G4-6303-01A-11D-1770-01): tumor purity 0.68, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,450 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:36,004,316–39,284,917, 83 genes, copy number 7–16 (within-gene range 1–16) (broad region; genes not listed).
- chr10:30,309,801–30,374,448, 1 gene, copy number 7 (within-gene range 2–7): MTPAP.
- chr10:30,353,706–32,056,839, 38 genes, copy number 7–9: DNM1P17, GOLGA2P6, RN7SL241P, MIR7162, NIFKP1, AL161651.1, CCND3P1, MAP3K8, HNRNPA1P32, AL590068.4, AL590068.1, RN7SL63P, AL590068.2, AL590068.3, LYZL2, SVIL2P, LINC02644, ZNF438, AL359532.1, DDX10P1, AL359546.1, LINC02664, ZEB1-AS1, RNA5SP309, ZEB1, SPTLC1P1, AL117340.1, AL161935.1, AL161935.3, AL161935.2, MACORIS, Y_RNA, ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, Y_RNA.
- chr13:18,467,172–26,698,804, 213 genes, copy number 7 (broad region; genes not listed).
- chr13:37,934,298–44,256,596, 109 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr20:2,075,555–3,410,036, 50 genes, copy number 11: RPL7P2, STK35, AL359916.1, AL121899.3, AL121899.4, AL121899.1, AL121899.2, TGM3, TGM6, Y_RNA, SNRPB, AL049650.1, ZNF343, TMC2, NOP56, MIR1292, SNORD110, SNORA51, SNORD86, SNORD56, SNORD57, IDH3B, AL049712.1, EBF4, RPL19P1, CPXM1, AL035460.1, C20orf141, TMEM239, PCED1A, VPS16, PTPRA, GNRH2, MRPS26, OXT, AVP, RN7SL555P, UBOX5-AS1, UBOX5, FASTKD5, LZTS3, DDRGK1, ITPA, SLC4A11, AL109976.1, C20orf194, RNU6-1019P, UBE2V1P1, U3, AL117334.1.
- chr20:25,195,693–64,313,132, 956 genes, copy number 8–14 (within-gene range 3–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 753. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
